Somatic mutation profile of tumor specimen TCGA-09-1664-01A (aliquot TCGA-09-1664-01A-01W-0639-09) from TCGA case TCGA-09-1664, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 37.6 years (13,739 days).
Specimen TCGA-09-1664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cef26712-db18-44a9-8f82-4a2adfa19452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1664-11A (Solid Tissue Normal), aliquot TCGA-09-1664-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7a03b38-5b17-488d-b013-e74b9a0e06e5

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C11orf42 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.025); catalogued as COSV56410111; called by muse, mutect2, varscan2
- COL4A4 | c.3214G>T p.G1072* | Nonsense Mutation (SNP) | VAF 124/257 reads (48%) | catalogued as COSV61630327; called by muse, mutect2, varscan2
- DMD | c.6983A>T p.K2328I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV58896894; called by muse, mutect2, varscan2
- KCNH7 | c.3071G>A p.S1024N | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1331574029, COSV59789901; called by muse, mutect2, varscan2
- MAGT1 | c.532-1G>T p.X178_splice (on ENST00000618282 / NM_001367916.1; = p.X210_splice on NM_032121.5) | Splice Site (SNP) | VAF 91/194 reads (47%) | catalogued as COSV63781086; called by muse, mutect2, varscan2
- NCR3 | c.291C>G p.D97E | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as COSV53000666; called by muse, mutect2, varscan2
- RB1CC1 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs751619561, COSV50244020; called by muse, mutect2, varscan2
- TAS2R1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV66778273; called by muse, mutect2, varscan2
- NF1 | c.238dup p.Y80Lfs*27 | Frame Shift Ins (INS) | VAF 27/40 reads (68%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.234G>A p.A78= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs758112002, COSV52392287; called by muse, mutect2, varscan2
- DOK5 | c.114T>C p.G38= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV52817757; called by muse, mutect2, varscan2
- KDM5C | c.4639C>T p.L1547= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV64763414; called by muse, mutect2, varscan2
- PDE10A | c.1041A>G p.T347= | Silent (SNP) | VAF 187/445 reads (42%) | catalogued as rs1391685085, COSV63092892; called by muse, mutect2, varscan2
- TMEM222 | c.600C>T p.T200= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as rs200116563, COSV65026947; called by muse, mutect2, varscan2
